Surgical pathology report (de-identified scan), TCGA case TCGA-NJ-A4YP, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Rush University, specimen TCGA-NJ-A4YP-01A (Primary Tumor).

[page 1 of 9]
Procedure Location:

1C1-0-3

adenocarcinoma, w/ mixed subtypes 8255/3

Site: lung @ lower lobe C343

W.

11/1/12

PATHOLOGY SURGICAL

Results

Entry Date

[page 2 of 9]
Component Results

PATHOLOGY RESULT:

Department of Pathology

Final

Clinical Data Repository* This report may not match the original report
format

FINAL DIAGNOSIS

A. (Level 7 lymph node, dissection): Fragments of lymph nodes, negative for malignancy.

[page 3 of 9]
B. (Level 11 lymph node, right, dissection): Fragments of lymph nodes, negative for malignancy.

C. (Level 11 lymph node, right, dissection): One lymph node, negative for malignancy. (0/1).

D. (Level 9 lymph node, right, dissection): One lymph node, negative for malignancy. (0/1).

E. (Right lower lobe, lobectomy): Invasive adenocarcinoma with papillary features, grade 3. Margins of resection are free of involvement. pT2aN0. See note.

F. (Level 11 lymph node, dissection): Fragments of lymph nodes, negative for malignancy.

G. (Level 10 right lymph node, dissection): Fragments of lymph nodes, negative for malignancy.

INTRAOPERATIVE CONSULTATION

[page 4 of 9]
E. FROZEN: RIGHT LOWER LOBE: Adenocarcinoma with focal mucinous features.

Bronchial margin negative for tumor. (E91 bronchial margin, E92 tumor)

NOTE

Lung Cancer Summary

Specimen type: Right lower lobectomy

Tumor location: Adjacent to main bronchus

Tumor size: 3.4 cm

Histologic type: Invasive adenocarcinoma with papillary features

Histologic grade: 3

Status of margins:

Bronchial: Negative

[page 5 of 9]
Vascular: Negative

Parenchymal: Negative

Pleural: Negative

Visceral/Parietal pleural invasion: Absent

Lymphatic vascular invasion: Absent

Lymph node status: Negative (Level 7,9R,10R,11R)

Extension into other structures: Absent

Non-neoplastic pathology: Post obstructive pneumonia

TMN stage: pT2aN0

GROSS DESCRIPTION

A. The specimen is labeled level 7 lymph node. Received are multiple fragments of pink-tan soft tissue measuring in aggregate 2.7 x 1.4 x 0.6 cm. The entire specimen is submitted in cassettes A1 and A2.

B. The specimen is labeled level 11 node, right. Received are multiple fragments of tan lymphoid tissue measuring in aggregate 3.1 x 1.4 x 0.5 cm.

[page 6 of 9]
The entire specimen is submitted in cassettes B1 and B2.

C. The specimen is labeled level 11 right lymph node. Received is a 0.6 x 0.3 x 0.3 cm lymph node. The specimen is entirely submitted in cassette C1.

D. The specimen is labeled level 9 lymph node. Received fresh is a 0.8 x 0.5 x 0.5 cm lymph node. The specimen is bisected and entirely submitted in cassette D1.

E. The specimen is labeled right lower lobe of lung. Received fresh for frozen section analysis is a 21.5 x 12.5 x 2.7 cm right lower lung lobe. In the lower posterior aspect of the lung there is a 3.4 x 2.1 x 1.9 cm firm white lung mass. This lung mass measures 2.4 cm from the bronchial margin of resection. The bronchi is opened showing a fungating tumor mass in its lumen.

The tumor measures 0.5 cm from the pleural resection margin. The adjacent lung to the tumor has mucus plugs in the bronchi and is focally consolidated.

There do not appear to be any additional nodules within the lung. The lung at the upper aspect of the lobe (away from the tumor) is crepitant and unremarkable in appearance. Representative sections are taken and submitted as follows: E1, vascular margin; E2, bronchus with adjacent tumor; E3, vessels with adjacent tumor; E4, tumor and adjacent normal; E5, tumor and inner parenchymal lymph nodes; E6, consolidated lung adjacent to tumor; E7, normal lung away from tumor; E8, hilar lymph node.

[page 7 of 9]
F. The specimen is labeled level 11 node. Received fresh is a 1.0 x 0.5 x 0.5 cm fragment of brown-tan lymph node with accompanying red-yellow fibroadipose tissue. The lymph node is bisected and submitted entirely in cassette F1.

G. The specimen is labeled level 10R. Received in formalin is a 0.5 x 0.2 x 0.2 cm brown-black possible fragment of lymph node with accompanying red soft fibrous tissue. The entire specimen is submitted in cassette G1.

SPECIMEN(S) RECEIVED

A: LEVEL 7 LYMPH NODE

B: LEVEL 11 NODE RIGHT

C: LEVEL 11 RIGHT NODE

D: LEVEL 9 NODE

E: FROZEN: RIGHT LOWER LOBE

F: LEVEL 11 NODE

G: LEVEL 10R

* The above listed tests (if any) were developed and the performance characteristics determined by _____ These tests have not been cleared or approved for commercial use by the U.S. Food and Drug Administration. The FDA has determined that FDA review is not required for such in-house assays.

[page 8 of 9]
OPERATIVE INFORMATION

**DIAGNOSIS: LUNG CANCER; PROCEDURE: BRONCHOSCOPY FLEXIBLE FIBEROPTIC,
THORACOSCOPY VIDEO ASSISTED**

INTRADEPARTMENT CONSULTATION PATHOLOGIST: QA COMMITTEE

The attending pathologist was physically present when this specimen was diagnosed, and actively participated in all key decisions.

Lab and Collection

PATHOLOGY SURGICAL

Lab and Collection Information

[page 9 of 9]
PATHOLOGY SURGICAL

Pathology

Procedure Location:

H/PAA Discrepancy		☒

Source: NCI Genomic Data Commons file cbc0036c-0232-4f09-9ff5-73b1f6e169fd (TCGA-NJ-A4YP.13552F62-0795-453F-A597-54B3214C6F24.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).